Somatic mutation profile of tumor specimen MMRF_2823_1_BM_CD138pos (aliquot MMRF_2823_1_BM_CD138pos_T1_KHS5U_L15711) from MMRF case MMRF_2823, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.0 years (19,366 days).
Specimen MMRF_2823_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99008da6-2ccf-4a04-8ba6-578068965135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2823_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2823_1_PB_WBC_C2_KHS5U_L15755; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3518c65f-8fc1-46fd-ac37-890717f2da4c

The open-access MAF lists 76 somatic variants for this specimen: 32 protein-altering or splice-affecting, 8 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 21, Silent 8, Intron 6, 3'Flank 3, RNA 3, 5'Flank 2, Splice Site 2, In Frame Del 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNTL1 | c.302T>C p.V101A | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs1214507654; called by muse, mutect2, varscan2
- DCT | c.547G>T p.D183Y | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373904310, COSV65471030; called by muse, mutect2, varscan2
- IGBP1P2 | c.614T>A p.I205N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs750741114; called by muse, mutect2, varscan2
- IGHJ3 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 30/35 reads (86%) | PolyPhen probably damaging (0.999); catalogued as rs376256350; called by muse, mutect2, varscan2
- IGHV2-70 | c.288A>C p.K96N | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as rs531218949; called by muse, varscan2
- NFKBIA | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755146648; called by muse, mutect2
- PNMA8B | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 84/268 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.545); catalogued as rs775611292; called by muse, mutect2, varscan2
- PRKDC | c.3833C>T p.A1278V | Missense Mutation (SNP) | VAF 66/126 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs368851152; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYMPK | c.2923G>T p.V975L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs372937364; called by muse, mutect2, varscan2
- ABRA | c.917T>A p.I306N | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALMS1 | c.935T>G p.F312C | Missense Mutation (SNP) | VAF 62/117 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- B9D1 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 57/107 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1orf131 | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 38/62 reads (61%) | SIFT tolerated (0.4); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- CD83 | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 74/153 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- COL6A3 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- DNAJC15 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN3A | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 53/173 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- KCNB1 | c.108C>A p.N36K | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRTAP4-12 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 96/247 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); called by muse, varscan2
- MBOAT7 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 84/119 reads (71%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MDN1 | c.402T>G p.N134K | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- MYDGF | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- OR13C3 | c.439A>C p.M147L | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SFTPC | c.358T>C p.C120R | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLC1A2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC8A1 | c.2756T>C p.F919S | Missense Mutation (SNP) | VAF 64/142 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- THBS3 | c.1880+2T>C p.X627_splice | Splice Site (SNP) | VAF 35/67 reads (52%) | called by muse, mutect2, varscan2
- TM4SF20 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- TMCO3 | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TRAF3 | c.269_277del p.A90_Q92del | In Frame Del (DEL) | VAF 73/83 reads (88%) | called by mutect2, pindel, varscan2
- VPS8 | c.1514A>C p.D505A (on ENST00000625842 / NM_001349294.1; = p.D503A on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); called by muse, mutect2
- ZFPM2 | c.965-2A>G p.X322_splice | Splice Site (SNP) | VAF 92/177 reads (52%) | called by muse, mutect2, varscan2
- ACTC1 | c.468C>T p.D156= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as COSV51761677; called by muse, mutect2, varscan2
- DNAH5 | c.3942C>T p.G1314= | Silent (SNP) | VAF 37/72 reads (51%) | catalogued as rs764970736, COSV54227337; called by muse, mutect2, varscan2
- OR13C3 | c.438C>A p.G146= | Silent (SNP) | VAF 88/256 reads (34%) | called by muse, mutect2, varscan2
- SH3KBP1 | c.1329C>T p.G443= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as rs1279065135; called by muse, mutect2, varscan2
- SHB | c.606C>T p.G202= | Silent (SNP) | VAF 50/113 reads (44%) | called by muse, mutect2, varscan2
- SHROOM1 | c.1506T>G p.P502= | Silent (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- TAP2 | c.1095G>A p.L365= | Silent (SNP) | VAF 85/190 reads (45%) | called by muse, mutect2, varscan2
- ZNF547 | c.1179T>A p.L393= | Silent (SNP) | VAF 43/172 reads (25%) | called by muse, mutect2, varscan2
- ABBA01000935.2 | n.489T>C | RNA (SNP) | VAF 58/129 reads (45%) | called by muse, mutect2, varscan2
- ANGPT1 | c.*77C>T | 3'UTR (SNP) | VAF 17/242 reads (7%) | called by muse, mutect2
- AP3M1 | c.*190G>A | 3'UTR (SNP) | VAF 35/55 reads (64%) | called by muse, mutect2, varscan2
- ARF6 | c.*53A>T | 3'UTR (SNP) | VAF 206/445 reads (46%) | called by muse, mutect2, varscan2
- BARHL1 | c.*230T>C | 3'UTR (SNP) | VAF 22/209 reads (11%) | called by muse, mutect2, varscan2
- C11orf87 | c.*3020C>A | 3'UTR (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- C2orf81 | c.28-128A>C | Intron (SNP) | VAF 50/110 reads (45%) | called by muse, varscan2
- CDK6 | c.*1654A>G | 3'UTR (SNP) | VAF 23/45 reads (51%) | catalogued as rs1234862860; called by muse, mutect2, varscan2
- DDC | c.944+2398C>T | Intron (SNP) | VAF 138/322 reads (43%) | catalogued as rs1461463539; called by muse, mutect2, varscan2
- DIO2 | c.*2332C>T | 3'UTR (SNP) | VAF 45/46 reads (98%) | called by muse, mutect2, varscan2
- EVC | c.*2807G>A | 3'UTR (SNP) | VAF 119/238 reads (50%) | called by muse, mutect2, varscan2
- GALNT17 | c.*243A>G | 3'UTR (SNP) | VAF 82/195 reads (42%) | called by muse, mutect2, varscan2
- H2BU1 | chr1:228464320 A>G | 3'Flank (SNP) | VAF 64/138 reads (46%) | called by muse, mutect2, varscan2
- HGF | c.482+973T>G | Intron (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2, varscan2
- HPRT1 | c.-128G>C | 5'UTR (SNP) | VAF 4/21 reads (19%) | catalogued as rs1298090374; called by muse, mutect2, varscan2
- IGF2BP1 | c.*4567_*4611del | 3'UTR (DEL) | VAF 42/130 reads (32%) | called by mutect2, pindel
- LDLR | c.*926G>A | 3'UTR (SNP) | VAF 95/263 reads (36%) | catalogued as rs142953361; called by muse, mutect2, varscan2
- MACROH2A1 | chr5:135334358 A>C | 3'Flank (SNP) | VAF 33/76 reads (43%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851246 C>A | 5'Flank (SNP) | VAF 84/197 reads (43%) | called by muse, mutect2, varscan2
- NDST3 | c.*261T>C | 3'UTR (SNP) | VAF 16/44 reads (36%) | catalogued as rs567758948; called by muse, mutect2, varscan2
- NHLH2 | c.*758A>G | 3'UTR (SNP) | VAF 21/24 reads (88%) | called by muse, mutect2, varscan2
- NKX2-3 | c.*534C>G | 3'UTR (SNP) | VAF 87/200 reads (44%) | called by muse, mutect2, varscan2
- NUCKS1 | c.*2524A>C | 3'UTR (SNP) | VAF 56/114 reads (49%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+3552A>G | Intron (SNP) | VAF 68/131 reads (52%) | catalogued as rs1364475259; called by muse, mutect2, varscan2
- OR5AK1P | n.38del | RNA (DEL) | VAF 72/191 reads (38%) | called by mutect2, pindel, varscan2
- PTER | c.*97C>A | 3'UTR (SNP) | VAF 32/89 reads (36%) | called by muse, mutect2
- RAX | c.*1263C>G | 3'UTR (SNP) | VAF 89/249 reads (36%) | called by muse, mutect2, varscan2
- RND3 | c.*11A>T | 3'UTR (SNP) | VAF 116/244 reads (48%) | called by muse, mutect2, varscan2
- RNF19B | chr1:32964729 A>C | 5'Flank (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- SCARB1 | chr12:124777553 G>A | 3'Flank (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- SCN5A | c.612-188G>A | Intron (SNP) | VAF 22/53 reads (42%) | catalogued as rs756895523, COSV61122464; called by muse, mutect2, varscan2
- SETD4 | c.-37+179T>C | Intron (SNP) | VAF 62/130 reads (48%) | called by muse, mutect2, varscan2
- SLC9A2 | c.*1116T>C | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- SMPD4BP | n.3295A>T | RNA (SNP) | VAF 13/26 reads (50%) | called by mutect2, varscan2
- TECRL | c.*67A>T | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- WDFY3 | c.*367dup | 3'UTR (INS) | VAF 37/95 reads (39%) | called by mutect2, pindel, varscan2
